Somatic mutation profile of tumor specimen MBCProject_4766_T1_WES (aliquot MBCProject_4766_T1_WES_1) from CMI case MBCProject_4766, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 63.0 years (23,014 days).
Specimen MBCProject_4766_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 156ea78f-b63b-46c8-a207-321800c4e995.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4766_SALIVA (Saliva), aliquot MBCProject_4766_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4bf0114-becc-4081-a76d-04a09fadaf96

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, Nonsense Mutation 2, Intron 2, Splice Region 1, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, varscan2
- DMBT1 | c.5420G>A p.C1807Y (on ENST00000338354 / NM_001377530.1; = p.C1050Y on NM_004406.3) | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353710; called by muse, mutect2, varscan2
- DMRTB1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as rs1409581070, COSV101008273; called by muse, mutect2, varscan2
- FBN2 | c.6227C>T p.P2076L | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV99331157; called by muse, mutect2, varscan2
- MXRA5 | c.4685C>T p.S1562F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1421078215, COSV99478000; called by muse, mutect2, varscan2
- MYH6 | c.4828C>T p.R1610C | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780726611; ClinVar: uncertain significance; called by muse, mutect2
- OPA3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.727); catalogued as COSV54397830, COSV54398681; called by muse, mutect2
- PBRM1 | c.2139del p.M713Ifs*18 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as COSV56272991; called by mutect2, pindel, varscan2
- RBAK | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs766173536, COSV62330981, COSV62332644; called by muse, mutect2, varscan2
- RNF39 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs776173276; called by muse, mutect2, varscan2
- SIPA1L1 | c.5203C>T p.P1735S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.253); catalogued as COSV62171887; called by muse, mutect2, varscan2
- THOC1 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 6/135 reads (4%) | catalogued as rs1268575439, COSV55275117; called by muse, mutect2
- TNR | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54893337; called by muse, mutect2, varscan2
- WDR3 | c.582A>T p.V194= | Splice Region (SNP) | VAF 45/142 reads (32%) | catalogued as rs140258611; called by muse, mutect2, varscan2
- ZNF407 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745947982; called by muse, mutect2, varscan2
- ZNF586 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.271); catalogued as rs1397463743; called by muse, mutect2
- ANKRD66 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CASKIN1 | c.164A>T p.H55L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CATSPER1 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, mutect2
- CCDC22 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRNA3 | c.283A>C p.K95Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FRY | c.2900T>A p.L967Q | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HES7 | c.138+2T>A p.X46_splice | Splice Site (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- KDM3A | c.151G>T p.V51F | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- KLHDC2 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASSF10 | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RCBTB2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TMC8 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ADAMTS9 | c.186C>T p.P62= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- ANKRD34B | c.453C>T p.I151= | Silent (SNP) | VAF 8/163 reads (5%) | catalogued as rs1285480765; called by muse, mutect2
- ATAD3C | c.1026G>A p.E342= | Silent (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- GABRP | c.1284A>G p.L428= | Silent (SNP) | VAF 18/57 reads (32%) | called by mutect2, varscan2
- NRG3 | c.675T>A p.P225= | Silent (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- PATE3 | c.273C>T p.Y91= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- NPEPPS | c.980+304A>T | Intron (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3283C>G | RNA (SNP) | VAF 46/216 reads (21%) | called by muse, mutect2, varscan2
- ZNF211 | c.90+300T>A | Intron (SNP) | VAF 62/293 reads (21%) | called by muse, mutect2, varscan2
